Somatic mutation profile of tumor specimen MP2PRT-PAUKWE-TMP1-A (aliquot MP2PRT-PAUKWE-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUKWE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,235 days).
Specimen MP2PRT-PAUKWE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b1952d-5941-4d6e-a357-b7def1eb79c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKWE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKWE-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a6c191f-75bf-41e2-8667-cc9605536593

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55605940; called by muse, mutect2
- COL26A1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 148/468 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1407929766; called by muse, mutect2, varscan2
- ADAMTS14 | c.2410G>T p.E804* | Nonsense Mutation (SNP) | VAF 20/449 reads (4%) | called by muse, mutect2
- PHF6 | c.448G>T p.E150* (on ENST00000332070 / NM_032458.3; = p.E151* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- TTN | c.92282C>T p.P30761L (on ENST00000591111; = p.P23337L on NM_003319.4) | Missense Mutation (SNP) | VAF 77/202 reads (38%) | PolyPhen benign (0.231); called by muse, mutect2, varscan2
- FLRT2 | c.1239C>T p.G413= | Silent (SNP) | VAF 143/433 reads (33%) | called by muse, mutect2, varscan2
- OR9K2 | c.582C>T p.C194= (on ENST00000305377; = p.C172= on NM_001005243.1) | Silent (SNP) | VAF 121/472 reads (26%) | catalogued as rs140070869; called by muse, mutect2, varscan2
